Surgical pathology report (de-identified scan), TCGA case TCGA-ZB-A96K, project TCGA-THYM (Thymoma), tissue source site Thoraxklinik, specimen TCGA-ZB-A96K-01A (Primary Tumor).

Name:

Identifier:

Unique Patient #:

Tumor Type : Thymoma

Pathology Report-Summary:

Material:

Tumor: 8.0 x 7.0 x 6.0 cm

Diagnosis:

Type A/B-Thymoma

pT1, pN0 (0/8)

Masaoka: I

ICD-3

Thymoma, Type AB
malignant 8582/3

Site: Thymus C37.9
4/2/14

Prior Malignancy History	prostate	✓

Source: NCI Genomic Data Commons file b8f7a375-7beb-40a5-b741-43c5e5da147c (TCGA-ZB-A96K.EEE72B63-57E5-48A3-9ECA-4B959FEA1A22.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).